Gene-level copy-number profile of tumor specimen MP2PRT-PARPMF-TMP1-A from MP2PRT case MP2PRT-PARPMF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,115 days).
Specimen MP2PRT-PARPMF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 451a8a8d-e02a-4899-89ab-31de704c13d1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARPMF-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/0ddbcd5d-2f77-4c01-b23d-94b24fd60589

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 2,155; copy number 2: 56,650; copy number 3: 1.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,922,753, 13 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5.
- chr2:89,078,010–89,078,784, 1 gene (within-gene range 0–1): IGKV2-14.
- chr2:89,134,975–89,192,752, 5 genes (within-gene range 0–1): IGKV2-19, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25.
- chr2:89,252,211–89,254,015, 2 genes: IGKV3-31, IGKV1-32.
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–1): IGKV1D-12.
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–1): TRGC1.
- chr7:38,273,587–38,311,808, 6 genes (within-gene range 0–1): TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr14:22,415,362–22,507,723, 39 genes (within-gene range 0–2): AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34.
- chr14:106,367,385–106,411,021, 8 genes (within-gene range 0–1): IGHVII-33-1, IGHV3-33-2, IGHV4-34, IGHV7-34-1, IGHV3-35, IGHV3-36, IGHV3-37, IGHV3-38.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–1): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.
- chr14:106,482,435–106,538,344, 9 genes (within-gene range 0–1): LINC00221, IGHVIV-44-1, IGHVII-44-2, IGHV1-45, IGHV1-46, IGHVII-46-1, IGHV3-47, IGHVIII-47-1, IGHV3-48.
- chr14:106,564,375–106,579,236, 3 genes (within-gene range 0–2): IGHVII-49-1, IGHV3-50, IGHV5-51.
- chr14:106,584,718–106,586,826, 2 genes (within-gene range 0–2): IGHVII-51-2, IGHV3-52.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 323. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
